CCDI case PBCGIB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d75aff74-6d0f-4a65-9efd-3e2117c676b2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (172 days).

Biospecimens (3 samples)
- Sample 0DR9BV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR9CF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR9CX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
